Somatic mutation profile of tumor specimen 0DOA3Q from CCDI case PBCCJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,861 days).
Specimen 0DOA3Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cc7311e-5958-49cd-951f-608cbfca9a1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOA28 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eba65586-0c36-4f22-b1fa-6b67f5f56d69

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO28 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1228327424; called by muse, mutect2
- MAGEB4 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1043294170, COSV64397382; called by muse, mutect2, varscan2
- PSD | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs774123668; called by muse, mutect2, varscan2
- PTPN12 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 34/708 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV50360534; called by muse, mutect2
- ABCA1 | c.1271G>C p.W424S | Missense Mutation (SNP) | VAF 36/712 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2
- KCTD15 | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AMPD2 | c.426C>G p.L142= | Silent (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- HECTD4 | c.7266C>T p.S2422= | Silent (SNP) | VAF 148/528 reads (28%) | called by muse, mutect2, varscan2
- SURF6 | c.462G>T p.R154= | Silent (SNP) | VAF 31/367 reads (8%) | called by muse, mutect2
